Somatic mutation profile of tumor specimen 5da00abd-5fa7-4deb-95f1-7982e0 (aliquot 5da00abd-5fa7-4deb-95f1-7982e0_D6_1) from CPTAC case 11CO027, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA.
Specimen 5da00abd-5fa7-4deb-95f1-7982e0: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2399a8cc-14e9-4375-a47e-81b46888f123.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 7afb9ddb-f1c1-40ac-9873-a34cc9 (Blood Derived Normal), aliquot 7afb9ddb-f1c1-40ac-9873-a34cc9_D1_2; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60519223-21c5-4806-8ab5-67de73979976

The open-access MAF lists 206 somatic variants for this specimen: 139 protein-altering or splice-affecting, 41 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 118, Silent 41, Intron 14, Frame Shift Del 7, In Frame Del 4, 3'UTR 4, Nonsense Mutation 4, 5'UTR 4, RNA 3, Splice Site 3, Splice Region 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.6259G>A p.G2087R | Missense Mutation (SNP) | VAF 114/418 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1553153748, COSV61371196, COSV61381160; ClinVar: other; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 13/38 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SOX9 | c.499_501del p.K167del | In Frame Del (DEL) | VAF 90/336 reads (27%) | hotspot (GDC flag); called by pindel, varscan2
- TP53 | c.644G>A p.S215N | Missense Mutation (SNP) | VAF 176/464 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587782177, COSV52679681, COSV52686793, COSV52700292, COSV52891297; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCC4 | c.2077G>C p.E693Q | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.091); catalogued as COSV100972448; called by muse, mutect2, varscan2
- ABLIM3 | c.1253G>A p.R418K | Missense Mutation (SNP) | VAF 57/321 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs1271071550; called by muse, mutect2, varscan2
- AGO4 | c.2174G>C p.R725T | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.348); catalogued as COSV100943037; called by muse, mutect2, varscan2
- ALDH5A1 | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 136/247 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768219929, CM1413045, COSV62374751; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMER3 | c.1081G>A p.G361S | Missense Mutation (SNP) | VAF 121/452 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.141); catalogued as rs367830628; called by muse, mutect2, varscan2
- APBA1 | c.230del p.R77Pfs*20 | Frame Shift Del (DEL) | VAF 37/156 reads (24%) | catalogued as COSV55238263; called by mutect2, pindel, varscan2
- APC | c.4037C>A p.S1346* | Nonsense Mutation (SNP) | VAF 97/277 reads (35%) | catalogued as COSV57325995, COSV57328373, COSV57364395; called by muse, mutect2, varscan2
- ARMH1 | c.148_150del p.E50del | In Frame Del (DEL) | VAF 44/161 reads (27%) | catalogued as rs1442637004; called by mutect2, varscan2
- BAIAP2 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.089); catalogued as rs745515587; called by muse, mutect2, varscan2
- CACNA1E | c.2555G>A p.R852H | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.215); catalogued as rs538192254, COSV62387759; called by muse, mutect2, varscan2
- CACNG7 | c.211C>A p.R71S | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as COSV55817202; called by muse, mutect2, varscan2
- CEP104 | c.1127C>A p.S376Y | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT tolerated (0.79); PolyPhen benign (0.055); catalogued as COSV65516289; called by mutect2, varscan2
- COL4A2 | c.2849G>C p.G950A | Missense Mutation (SNP) | VAF 34/216 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64628883; called by muse, mutect2, varscan2
- COL6A1 | c.2659G>C p.E887Q | Missense Mutation (SNP) | VAF 53/570 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.114); catalogued as rs780234826, CM141367, COSV62611731; called by muse, mutect2
- COL9A2 | c.1340C>T p.A447V | Missense Mutation (SNP) | VAF 86/341 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.159); catalogued as rs1462203433; called by muse, mutect2, varscan2
- DNAAF3 | c.931C>G p.Q311E (on ENST00000524407 / NM_001256715.2; = p.Q358E on NM_178837.4) | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.074); catalogued as rs1435089653, COSV100787947; called by muse, mutect2, varscan2
- DRP2 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 39/218 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1282399803, COSV65812189; called by muse, mutect2, varscan2
- DYSF | c.5342G>C p.G1781A | Missense Mutation (SNP) | VAF 69/273 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs886042341; called by muse, mutect2, varscan2
- EMC1 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 52/185 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746537714, COSV61886968; called by muse, mutect2, varscan2
- ETNPPL | c.316_319del p.C106Ifs*12 | Frame Shift Del (DEL) | VAF 11/84 reads (13%) | catalogued as rs753551149; called by pindel, varscan2
- FAM204A | c.338A>G p.E113G | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.178); catalogued as rs1466026033; called by muse, mutect2, varscan2
- FAT3 | c.1639G>T p.V547F | Missense Mutation (SNP) | VAF 66/248 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53154173, COSV99973270; called by muse, mutect2, varscan2
- FAT3 | c.8193G>C p.R2731S | Missense Mutation (SNP) | VAF 96/361 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as COSV99967782; called by mutect2, varscan2
- GPER1 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 226/519 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as rs1179693461, COSV99867029; called by muse, mutect2, varscan2
- HECW1 | c.3170G>A p.R1057H | Missense Mutation (SNP) | VAF 61/261 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as rs374489291; called by muse, mutect2, varscan2
- KMT2C | c.13013T>G p.V4338G | Missense Mutation (SNP) | VAF 29/212 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as COSV51436694; called by muse, mutect2, varscan2
- LRFN5 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53246766; called by muse, mutect2, varscan2
- MEF2B | c.244A>G p.T82A | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV50765680; called by muse, mutect2, varscan2
- MN1 | c.2948G>T p.G983V | Missense Mutation (SNP) | VAF 72/229 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as COSV100179806; called by muse, mutect2, varscan2
- MTRF1 | c.1012G>C p.E338Q | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as COSV65263169; called by muse, mutect2, varscan2
- MVP | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as rs756111485, COSV62421637; called by muse, mutect2, varscan2
- NRDC | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.309); catalogued as rs747782025, COSV100703863; called by muse, mutect2, varscan2
- NUP210L | c.871C>T p.H291Y | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as rs1336806202; called by muse, mutect2, varscan2
- OR8K3 | c.243G>T p.M81I | Missense Mutation (SNP) | VAF 66/320 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.078); catalogued as rs905125363, COSV100449700, COSV57132293; called by muse, mutect2, varscan2
- POLR2B | c.3425A>G p.N1142S | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55276153; called by muse, mutect2, varscan2
- PRDM13 | c.1372G>C p.V458L | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100980589; called by muse, mutect2, varscan2
- PTPRQ | c.2699C>A p.P900H (on ENST00000616559; = p.P858H on NM_001145026.2) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1335950364; called by muse, varscan2
- R3HDM1 | c.2675C>T p.S892L | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs778060309; called by muse, mutect2, varscan2
- RASA3 | c.1370_1372del p.F457del | In Frame Del (DEL) | VAF 36/266 reads (14%) | catalogued as rs767949177; called by pindel, varscan2
- RASSF2 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as rs1294947532, COSV65082812; called by muse, mutect2
- RELN | c.10232A>G p.N3411S | Missense Mutation (SNP) | VAF 45/244 reads (18%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.613); catalogued as rs747044548; called by muse, mutect2, varscan2
- SEMA3E | c.1997G>A p.R666H | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.731); catalogued as rs779454555, COSV100319243; called by muse, mutect2
- SLC17A8 | c.1543C>G p.L515V | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT tolerated (0.85); PolyPhen benign (0.045); catalogued as COSV60123113, COSV60124368; called by mutect2, varscan2
- SLC26A7 | c.70A>G p.I24V | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs746463705; called by muse, mutect2, varscan2
- SLIT2 | c.1765C>A p.L589I | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV56567190; called by muse, mutect2, varscan2
- SOX18 | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 48/258 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs781360023; called by muse, mutect2, varscan2
- SYCP2 | c.3071del p.N1024Tfs*26 | Frame Shift Del (DEL) | VAF 10/53 reads (19%) | catalogued as rs753462162; called by mutect2, varscan2
- TCERG1L | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761569207, COSV64054630, COSV64058439; called by muse, mutect2, varscan2
- TMEM74 | c.181A>C p.S61R | Missense Mutation (SNP) | VAF 31/203 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV52462789; called by muse, mutect2, varscan2
- TOX | c.563G>C p.S188T | Missense Mutation (SNP) | VAF 65/444 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.351); catalogued as COSV63850301; called by muse, mutect2, varscan2
- TRAM1L1 | c.917C>T p.T306M | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.498); catalogued as rs1438967530, COSV60292155; called by muse, mutect2, varscan2
- TRPC5 | c.367G>A p.G123R | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.815); catalogued as rs755743430, COSV53283992; called by muse, mutect2, varscan2
- WDR13 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54332020; called by muse, mutect2, varscan2
- WWP1 | c.1180C>A p.R394S | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as COSV55357961; called by muse, mutect2, varscan2
- ZNF667 | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as rs139557092, COSV52639954; called by muse, mutect2, varscan2
- ZNF729 | c.1723G>T p.E575* | Nonsense Mutation (SNP) | VAF 62/234 reads (26%) | catalogued as COSV62605741; called by mutect2, varscan2
- ABCA2 | c.4234G>A p.A1412T (on ENST00000614293; = p.A1382T on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 141/442 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ABHD17A | c.686_688del p.Y229del (on ENST00000292577 / NM_001130111.2; = p.Y280del on NM_031213.4) | In Frame Del (DEL) | VAF 116/495 reads (23%) | called by pindel, varscan2
- AC244197.3 | c.190G>T p.D64Y | Missense Mutation (SNP) | VAF 63/508 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ACAN | c.1660G>T p.G554W | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADH1A | c.307A>T p.I103F | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AKR1B15 | c.187G>T p.A63S | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- AMY2A | c.1130A>T p.N377I | Missense Mutation (SNP) | VAF 44/422 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.195); called by muse, mutect2
- ANAPC4 | c.1868T>A p.F623Y | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANK1 | c.4357C>T p.L1453F | Missense Mutation (SNP) | VAF 88/560 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- ARHGAP9 | c.2237C>T p.T746I (on ENST00000393797 / NM_001319850.2; = p.T727I on NM_032496.4) | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ARMH3 | c.1607C>A p.T536K | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ASH1L | c.7913C>A p.P2638H (on ENST00000368346 / NM_001366177.2; = p.P2633H on NM_018489.3) | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ATP13A1 | c.662A>C p.K221T | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ATRX | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- BRDT | c.1369A>G p.K457E | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.006); called by muse, mutect2
- BRWD3 | c.3078C>A p.D1026E | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CCDC168 | c.6523T>C p.Y2175H | Missense Mutation (SNP) | VAF 59/351 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CCDC88A | c.3456_3457del p.Y1153* | Frame Shift Del (DEL) | VAF 28/171 reads (16%) | called by pindel, varscan2
- CCNB3 | c.3062C>G p.T1021S | Missense Mutation (SNP) | VAF 85/520 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.043); called by mutect2, varscan2
- CKAP4 | c.423C>G p.H141Q | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CPEB3 | c.1912G>A p.E638K | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- CYP2R1 | c.1224C>G p.H408Q | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP7A1 | c.754A>T p.S252C | Missense Mutation (SNP) | VAF 68/478 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DACH2 | c.1297A>T p.T433S | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- DDX53 | c.1256T>A p.L419H | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- DUSP16 | c.706T>C p.S236P | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- DYNC2H1 | c.12117A>T p.E4039D | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- EFCAB5 | c.1044+2_1044+5del p.X348_splice | Splice Site (DEL) | VAF 13/73 reads (18%) | called by mutect2, pindel, varscan2
- ELF1 | c.1346C>A p.T449K | Missense Mutation (SNP) | VAF 58/285 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ELK1 | c.508C>T p.Q170* | Nonsense Mutation (SNP) | VAF 120/657 reads (18%) | called by muse, mutect2, varscan2
- ELMO3 | c.1722-2_1722-1del p.X574_splice (on ENST00000652269; = p.X521_splice on NM_024712.5) | Splice Site (DEL) | VAF 34/399 reads (9%) | called by mutect2, pindel
- EMC4 | c.112del p.Q38Rfs*45 | Frame Shift Del (DEL) | VAF 50/204 reads (25%) | called by pindel, varscan2
- FRMD4A | c.65G>A p.C22Y | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- GCGR | c.658-5A>T | Splice Region (SNP) | VAF 164/516 reads (32%) | called by mutect2, varscan2
- GCN1 | c.1845C>G p.H615Q | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.011); called by mutect2, varscan2
- HDLBP | c.2828del p.G943Afs*35 | Frame Shift Del (DEL) | VAF 59/220 reads (27%) | called by mutect2, pindel, varscan2
- HIC2 | c.473G>C p.R158P | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- IFI44 | c.707T>C p.I236T | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- ITGA4 | c.2176A>T p.I726F | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LXN | c.574A>T p.I192F | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- MAST4 | c.1534A>T p.T512S (on ENST00000403625 / NM_001164664.2; = p.T323S on NM_015183.3) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- METTL24 | c.1016C>G p.S339C | Missense Mutation (SNP) | VAF 59/212 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- MSH3 | c.3131-22_3133delinsCA p.X1044_splice | Splice Site (DEL) | VAF 13/62 reads (21%) | called by pindel, varscan2*
- MXRA5 | c.871A>G p.S291G | Missense Mutation (SNP) | VAF 47/279 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NAA16 | c.830T>G p.L277R | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- NCKAP5 | c.345G>T p.M115I | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- PAK3 | c.788A>G p.D263G (on ENST00000262836 / NM_001324328.2; = p.D248G on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/323 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- PCDH11X | c.2543dup p.N848Kfs*6 | Frame Shift Ins (INS) | VAF 69/386 reads (18%) | called by mutect2, pindel, varscan2
- PCDH11X | c.3033+7A>G | Splice Region (SNP) | VAF 20/244 reads (8%) | called by muse, mutect2
- PDGFRL | c.590G>C p.R197P | Missense Mutation (SNP) | VAF 20/312 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- PDZK1 | c.434A>G p.Y145C | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PHEX | c.1571C>G p.A524G | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PNMA8A | c.1225C>T p.Q409* | Nonsense Mutation (SNP) | VAF 17/71 reads (24%) | called by muse, mutect2, varscan2
- POLA1 | c.2710C>A p.P904T | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PPP1R9A | c.1497G>T p.K499N | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PTPN13 | c.2681A>C p.Q894P | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2
- RBP3 | c.2097G>T p.L699F | Missense Mutation (SNP) | VAF 128/541 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by mutect2, varscan2
- RDX | c.917A>G p.K306R | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RNF2 | c.748A>T p.T250S | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- RPH3A | c.2009A>T p.E670V (on ENST00000389385 / NM_001143854.2; = p.E666V on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- RYR2 | c.4627G>C p.V1543L | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- RYR2 | c.6682G>C p.G2228R | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCN2A | c.3323C>A p.A1108D | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- SLC5A11 | c.20G>C p.S7T | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SQLE | c.269del p.K90Rfs*20 | Frame Shift Del (DEL) | VAF 9/77 reads (12%) | called by mutect2, pindel, varscan2
- TAS1R2 | c.2210T>A p.L737Q | Missense Mutation (SNP) | VAF 172/673 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by mutect2, varscan2
- TENM4 | c.5989C>A p.H1997N | Missense Mutation (SNP) | VAF 78/311 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TET3 | c.1012C>A p.P338T | Missense Mutation (SNP) | VAF 62/518 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- THNSL1 | c.1265G>A p.G422D | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.224); called by muse, mutect2
- THSD7B | c.2143A>T p.T715S | Missense Mutation (SNP) | VAF 63/233 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- TP53I13 | c.553C>G p.P185A | Missense Mutation (SNP) | VAF 84/312 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- USF3 | c.6035C>T p.P2012L | Missense Mutation (SNP) | VAF 61/243 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UTP15 | c.1024A>C p.K342Q | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- VPS11 | c.297A>T p.K99N (on ENST00000620429; = p.K643N on NM_021729.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/189 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- ZBED5 | c.739A>G p.T247A | Missense Mutation (SNP) | VAF 74/325 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZEB2 | c.2375C>T p.S792F | Missense Mutation (SNP) | VAF 77/326 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZFP2 | c.270T>G p.I90M | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- ZNF112 | c.601A>G p.I201V (on ENST00000337401 / NM_001083335.2; = p.I195V on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/280 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, varscan2
- ZNF568 | c.1573C>T p.H525Y | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCC1 | c.1290C>T p.D430= | Silent (SNP) | VAF 26/106 reads (25%) | catalogued as rs371886235, COSV60683300; called by muse, mutect2, varscan2
- ACACB | c.4224C>T p.S1408= | Silent (SNP) | VAF 68/256 reads (27%) | catalogued as rs759946321, COSV100622673, COSV100622915; called by muse, mutect2, varscan2
- ACADSB | c.9C>T p.G3= | Silent (SNP) | VAF 39/181 reads (22%) | catalogued as rs1473575588, COSV62551089; called by muse, mutect2, varscan2
- ADGRG2 | c.2400G>T p.L800= (on ENST00000379869 / NM_001079858.3; = p.L797= on NM_005756.4) | Silent (SNP) | VAF 32/225 reads (14%) | catalogued as COSV100492445; called by mutect2, varscan2
- ADRA1D | c.795G>T p.L265= | Silent (SNP) | VAF 71/381 reads (19%) | called by muse, mutect2, varscan2
- ANKAR | c.1947A>G p.S649= | Silent (SNP) | VAF 34/122 reads (28%) | catalogued as rs780314972; called by muse, mutect2, varscan2
- ARHGAP40 | c.117C>T p.I39= | Silent (SNP) | VAF 30/176 reads (17%) | called by muse, mutect2
- ATP8B3 | c.3381C>T p.S1127= | Silent (SNP) | VAF 111/360 reads (31%) | catalogued as rs1244934508; called by muse, mutect2, varscan2
- CCR9 | c.567C>A p.I189= (on ENST00000357632 / NM_031200.3; = p.I177= on NM_006641.4) | Silent (SNP) | VAF 63/238 reads (26%) | called by mutect2, varscan2
- CNTNAP5 | c.2373C>T p.N791= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs566175180, COSV70474787; called by muse, mutect2, varscan2
- DENND1B | c.243A>G p.R81= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as rs1208382289; called by muse, mutect2, varscan2
- DNAH11 | c.7863C>T p.V2621= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as rs755501742, COSV60972826, COSV60985085; called by muse, mutect2, varscan2
- DUSP29 | c.63G>A p.S21= | Silent (SNP) | VAF 46/211 reads (22%) | catalogued as rs753100176, COSV58300922; called by muse, mutect2, varscan2
- FHOD1 | c.1176C>G p.T392= | Silent (SNP) | VAF 14/95 reads (15%) | called by muse, mutect2, varscan2
- FTHL17 | c.231C>T p.R77= | Silent (SNP) | VAF 120/602 reads (20%) | catalogued as COSV100784463; called by muse, mutect2, varscan2
- FTL | c.384C>T p.D128= | Silent (SNP) | VAF 33/330 reads (10%) | called by muse, mutect2, varscan2
- GPM6B | c.621T>A p.S207= | Silent (SNP) | VAF 12/199 reads (6%) | called by muse, mutect2
- HACE1 | c.1131A>G p.E377= | Silent (SNP) | VAF 28/52 reads (54%) | catalogued as rs777277931; called by muse, mutect2, varscan2
- HLA-DPB1 | c.234G>A p.T78= | Silent (SNP) | VAF 123/218 reads (56%) | called by muse, mutect2
- IL17RD | c.1632C>T p.V544= | Silent (SNP) | VAF 78/281 reads (28%) | catalogued as rs1479989426; called by muse, mutect2, varscan2
- JRKL | c.633C>T p.I211= | Silent (SNP) | VAF 26/222 reads (12%) | called by muse, mutect2, varscan2
- MROH2A | c.3258C>G p.L1086= | Silent (SNP) | VAF 40/150 reads (27%) | called by muse, mutect2, varscan2
- MUC16 | c.1128A>T p.I376= | Silent (SNP) | VAF 81/319 reads (25%) | called by muse, mutect2, varscan2
- MUC5B | c.10353G>A p.T3451= | Silent (SNP) | VAF 154/1308 reads (12%) | catalogued as rs556115696; called by mutect2, varscan2
- MYRIP | c.1314C>G p.A438= | Silent (SNP) | VAF 28/280 reads (10%) | called by muse, mutect2
- NDUFA3 | c.21C>T p.A7= | Silent (SNP) | VAF 36/116 reads (31%) | called by muse, mutect2, varscan2
- NLRP3 | c.2286G>T p.T762= | Silent (SNP) | VAF 88/296 reads (30%) | catalogued as rs199765599; called by muse, varscan2
- NR6A1 | c.543G>C p.G181= (on ENST00000487099 / NM_033334.4; = p.G177= on NM_001489.5) | Silent (SNP) | VAF 23/100 reads (23%) | called by muse, mutect2, varscan2
- OR5L2 | c.438T>G p.S146= | Silent (SNP) | VAF 67/310 reads (22%) | called by muse, mutect2, varscan2
- PCM1 | c.417G>A p.K139= | Silent (SNP) | VAF 21/179 reads (12%) | catalogued as rs1448812309, COSV61517723; called by muse, mutect2
- PDE6C | c.310C>A p.R104= | Silent (SNP) | VAF 102/388 reads (26%) | catalogued as CM110536, COSV65116838; called by muse, mutect2, varscan2
- PDE7B | c.720T>G p.S240= | Silent (SNP) | VAF 74/112 reads (66%) | catalogued as COSV100367682; called by muse, mutect2, varscan2
- POLA1 | c.2709T>C p.D903= | Silent (SNP) | VAF 11/51 reads (22%) | called by muse, mutect2, varscan2
- PREX1 | c.4482C>T p.N1494= | Silent (SNP) | VAF 227/424 reads (54%) | catalogued as rs375390695; called by muse, mutect2, varscan2
- RFTN1 | c.936C>T p.S312= | Silent (SNP) | VAF 70/235 reads (30%) | catalogued as rs763925708; called by muse, mutect2, varscan2
- S1PR1 | c.426C>G p.R142= | Silent (SNP) | VAF 120/481 reads (25%) | called by muse, mutect2, varscan2
- SCEL | c.69C>T p.T23= | Silent (SNP) | VAF 72/205 reads (35%) | called by muse, mutect2, varscan2
- SIRPA | c.1101T>C p.S367= | Silent (SNP) | VAF 26/152 reads (17%) | called by muse, mutect2, varscan2
- SPEG | c.1650C>T p.P550= | Silent (SNP) | VAF 18/75 reads (24%) | called by muse, mutect2, varscan2
- STAMBPL1 | c.120C>T p.I40= | Silent (SNP) | VAF 21/259 reads (8%) | called by muse, mutect2
- TRO | c.1122C>T p.N374= | Silent (SNP) | VAF 22/145 reads (15%) | catalogued as rs781658078; called by muse, mutect2, varscan2
- AC136604.1 | n.644G>A | RNA (SNP) | VAF 58/731 reads (8%) | catalogued as rs745332624; called by muse, mutect2
- ATP5MC1 | c.-2A>C | 5'UTR (SNP) | VAF 29/99 reads (29%) | catalogued as COSV100582388; called by muse, mutect2, varscan2
- C8orf82 | c.157-301G>T | Intron (SNP) | VAF 27/167 reads (16%) | called by muse, mutect2, varscan2
- CCM2 | c.*172G>A | 3'UTR (SNP) | VAF 134/335 reads (40%) | catalogued as rs758382740; called by muse, mutect2, varscan2
- COG4 | c.1002+44C>T | Intron (SNP) | VAF 97/321 reads (30%) | catalogued as rs770367353; called by muse, mutect2, varscan2
- CRYL1 | c.633+118G>T | Intron (SNP) | VAF 47/242 reads (19%) | called by muse, mutect2, varscan2
- DKK4 | c.*21dup | 3'UTR (INS) | VAF 13/76 reads (17%) | called by mutect2, pindel, varscan2
- EIF4G1 | c.-91-24G>T | Intron (SNP) | VAF 127/464 reads (27%) | called by muse, mutect2, varscan2
- EYS | c.1767-8223G>T | Intron (SNP) | VAF 14/70 reads (20%) | called by mutect2, varscan2
- FAM131B | c.91-50C>T | Intron (SNP) | VAF 79/422 reads (19%) | catalogued as rs372186934; called by muse, mutect2, varscan2
- ING1 | chr13:110712807 del CCA | 5'Flank (DEL) | VAF 51/255 reads (20%) | called by mutect2, pindel, varscan2
- LMLN | c.1232+3742C>A | Intron (SNP) | VAF 17/79 reads (22%) | called by muse, mutect2, varscan2
- MAN2B1 | c.1645-19C>T | Intron (SNP) | VAF 19/68 reads (28%) | catalogued as rs1228497674; called by muse, mutect2, varscan2
- MMP16 | c.1222+5111A>T | Intron (SNP) | VAF 22/94 reads (23%) | called by muse, mutect2, varscan2
- OTUB1 | c.-212C>A | 5'UTR (SNP) | VAF 14/46 reads (30%) | called by muse, mutect2, varscan2
- POM121L7P | n.726C>T | RNA (SNP) | VAF 12/68 reads (18%) | called by mutect2, varscan2
- RUFY2 | c.689+75_689+81del | Intron (DEL) | VAF 12/34 reads (35%) | called by mutect2, pindel, varscan2
- SFSWAP | c.2409-1339G>A | Intron (SNP) | VAF 15/52 reads (29%) | catalogued as rs768566125; called by muse, varscan2
- SSUH2 | n.421G>C | RNA (SNP) | VAF 32/80 reads (40%) | called by muse, varscan2
- STEAP3 | c.1185+2788G>T | Intron (SNP) | VAF 30/109 reads (28%) | called by muse, mutect2, varscan2
- TGFBR3 | c.*609G>T | 3'UTR (SNP) | VAF 77/304 reads (25%) | called by muse, mutect2, varscan2
- UQCRC2 | c.332+792_332+795del | Intron (DEL) | VAF 5/33 reads (15%) | called by pindel, varscan2
- USP16 | c.1179+76C>A | Intron (SNP) | VAF 17/48 reads (35%) | called by muse, mutect2, varscan2
- WNT7A | c.*24C>T | 3'UTR (SNP) | VAF 20/67 reads (30%) | catalogued as rs773811882; called by muse, mutect2, varscan2
- ZNF81 | c.-105C>T | 5'UTR (SNP) | VAF 48/319 reads (15%) | called by muse, mutect2, varscan2
- ZNF829 | c.-23del | 5'UTR (DEL) | VAF 26/135 reads (19%) | called by mutect2, pindel, varscan2
